Somatic mutation profile of tumor specimen TCGA-KC-A4BV-01A (aliquot TCGA-KC-A4BV-01A-31D-A26M-08) from TCGA case TCGA-KC-A4BV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.1 years (24,138 days).
Specimen TCGA-KC-A4BV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f6e07ae-fe2c-44a9-82a5-fdeea603617a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KC-A4BV-10A (Blood Derived Normal), aliquot TCGA-KC-A4BV-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7dfc587-9c76-43f7-9c1a-0d378b28b933

The open-access MAF lists 33 somatic variants for this specimen: 29 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 25, Silent 4, Frame Shift Ins 3, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.3497T>C p.I1166T (on ENST00000404938 / NM_001163941.2; = p.I721T on NM_178559.6) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV51704240; called by muse, mutect2
- ADGRV1 | c.11797C>T p.P3933S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101315573; called by muse, mutect2, varscan2
- AKNAD1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs202065262, COSV62201555; called by muse, mutect2, varscan2
- C1orf87 | c.1566C>G p.D522E | Missense Mutation (SNP) | VAF 58/232 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV100966955; called by muse, mutect2, varscan2
- CCDC186 | c.671T>C p.V224A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as rs1468233386, COSV100990994; called by muse, mutect2, varscan2
- CREBBP | c.6067C>G p.Q2023E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.042); catalogued as COSV99268870; called by muse, mutect2, varscan2
- IFIT2 | c.826T>A p.Y276N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.089); catalogued as COSV99259967; called by muse, mutect2, varscan2
- KLHL4 | c.1960G>C p.A654P | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100909238; called by muse, varscan2
- MYO9A | c.2192A>G p.D731G | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.764); catalogued as COSV100612819; called by muse, mutect2, varscan2
- NKAPD1 | c.125A>G p.D42G | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV99735287; called by muse, varscan2
- OR11H1 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs754609644, COSV99421640; called by muse, mutect2, varscan2
- PCMTD2 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs750037182, COSV100204041; called by muse, mutect2, varscan2
- PDPR | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 40/319 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99847871; called by muse, mutect2, varscan2
- PHIP | c.1639A>G p.S547G | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.235); catalogued as COSV99243555; called by muse, mutect2, varscan2
- PLA2G4F | c.1180G>A p.V394I | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.172); catalogued as COSV99300378; called by muse, mutect2
- PSG1 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.623); catalogued as rs150536125; called by muse, mutect2, varscan2
- PSMC6 | c.97C>T p.H33Y (on ENST00000612399; = p.H19Y on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.907); catalogued as COSV101471186; called by muse, mutect2, varscan2
- RP1 | c.6169C>G p.Q2057E | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs201860457, COSV99606519; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA3E | c.1720G>C p.G574R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100317607, COSV57089815, COSV57100301; called by muse, mutect2, varscan2
- SMOX | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 44/198 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV99602939; called by muse, mutect2, varscan2
- SPAM1 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99772766; called by muse, mutect2, varscan2
- STAG1 | c.801G>C p.L267F | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99364665; called by muse, mutect2, varscan2
- TATDN3 | c.637A>G p.I213V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1243624227, COSV100875190; called by muse, mutect2, varscan2
- UBQLN4 | c.1637_1638insT p.S547Kfs*29 | Frame Shift Ins (INS) | VAF 10/37 reads (27%) | catalogued as COSV100849287; called by mutect2, pindel, varscan2
- ZMYM3 | c.3658T>G p.F1220V | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100077540; called by muse, mutect2, varscan2
- ZWINT | c.624G>T p.R208S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as COSV100571485; called by muse, mutect2, varscan2
- CARS2 | c.1692_*3del | Nonstop Mutation (DEL) | VAF 24/119 reads (20%) | called by mutect2, pindel, varscan2
- OASL | c.11dup p.M4Ifs*6 | Frame Shift Ins (INS) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- PTEN | c.507dup p.S170Qfs*10 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, pindel, varscan2
- DUOX1 | c.1452G>A p.G484= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV100367695; called by muse, mutect2, varscan2
- GRPR | c.198T>C p.C66= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs765898530, COSV100977635; called by muse, mutect2, varscan2
- PCDHB1 | c.1386A>C p.R462= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100128052; called by muse, mutect2, varscan2
- UNC13D | c.828C>T p.C276= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV99256163; called by muse, mutect2, varscan2
